CCG case CUPP-B527 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cf8a57a6-2780-48ac-9f49-0a3ed1aada27

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Finland; Year of birth: 1937; Vital status: Dead; Days to death: 4,204 days (11.5 years); Year of death: 2012.

Diagnoses (1)
1. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: metastasis; Age at diagnosis: 62.8 years (22,937 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T0; AJCC clinical N: N1; AJCC clinical M: M0; AJCC pathologic T: T0; AJCC pathologic N: N1; AJCC pathologic M: M0; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Head, Face or Neck, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 15; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R0; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 2,882 days (7.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 4,204.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 70 kg; Height: 172 cm; BMI: 23.7.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 40.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B527-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B527-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample CUPP-B527-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B527-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
